Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6803, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6803-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Stomach
Tumor size: 4.5 x 5 x 1.2 cm
Tumor features: None specified
Histologic type: Adenocarcinoma
Histologic grade: Undifferentiated
Tumor extent: Adjacent structures
(specify) - greater omentum
Lymph nodes: 0/4 positive for
metastasis (Regional 0/4)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment:
Not specified
Additional pathologic findings: Not
specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file b9273337-5d53-414e-ae59-58d1defafa4b (TCGA-BR-6803.C80761A5-EBE7-4B8B-929D-0DEA5027310B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).